Somatic mutation profile of tumor specimen TCGA-EM-A2CU-01A (aliquot TCGA-EM-A2CU-01A-12D-A17V-08) from TCGA case TCGA-EM-A2CU, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 47.2 years (17,231 days).
Specimen TCGA-EM-A2CU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce7fcbcf-2eb2-44cf-95f2-3b99645a422a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2CU-10A (Blood Derived Normal), aliquot TCGA-EM-A2CU-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da6c719d-ebfa-4778-9ee5-5dc5ea022a15

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHSY3 | c.2089A>T p.R697* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV59280580; called by muse, mutect2, varscan2
- PATJ | c.4265C>G p.S1422* | Nonsense Mutation (SNP) | VAF 4/51 reads (8%) | catalogued as COSV56251460; called by muse, mutect2
- ARHGEF6 | c.402C>T p.N134= | Silent (SNP) | VAF 60/155 reads (39%) | catalogued as COSV51692855; called by muse, mutect2, varscan2
- HNRNPR | c.834C>T p.L278= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV56422689; called by mutect2, varscan2
